Somatic mutation profile of tumor specimen MP2PRT-PATDGG-TMP1-A (aliquot MP2PRT-PATDGG-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PATDGG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,492 days).
Specimen MP2PRT-PATDGG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e5173eb-c458-48c3-9e03-022dd9268417.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATDGG-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATDGG-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ee219d6-719a-4308-a2f9-7b07febca702

The open-access MAF lists 23 somatic variants for this specimen: 21 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 18, Silent 2, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 67/209 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASTN1 | c.2556C>A p.F852L | Missense Mutation (SNP) | VAF 131/328 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56060626; called by muse, mutect2, varscan2
- CATSPER2 | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 3/17 reads (18%) | catalogued as rs747240025, COSV100390506; called by mutect2, varscan2
- CREB5 | c.290G>A p.R97Q (on ENST00000357727 / NM_182898.4; = p.R90Q on NM_004904.3) | Missense Mutation (SNP) | VAF 133/318 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142741982, COSV63219001; called by muse, mutect2, varscan2
- GLIS3 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 105/302 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as rs768779690, COSV60926685; called by muse, mutect2, varscan2
- HEPH | c.3422G>A p.R1141H (on ENST00000343002; = p.R874H on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/398 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as rs746393868, COSV100294680, COSV57959332; called by muse, varscan2
- OBSCN | c.19747G>A p.V6583I | Missense Mutation (SNP) | VAF 303/659 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs545088568; called by muse, mutect2, varscan2
- PHF21B | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 309/999 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234257200; called by muse, mutect2, varscan2
- PTPRM | c.2641C>T p.R881W | Missense Mutation (SNP) | VAF 40/982 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756126322; called by muse, mutect2
- PTPRT | c.2826C>A p.Y942* | Nonsense Mutation (SNP) | VAF 195/446 reads (44%) | catalogued as rs1450021559; called by muse, mutect2, varscan2
- SEC14L4 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 40/946 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as rs757455217; called by muse, mutect2
- SRGAP3 | c.2926C>T p.R976W | Missense Mutation (SNP) | VAF 219/624 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1353283892, COSV64530566; called by muse, mutect2, varscan2
- TMEM211 | c.445C>T p.R149W (on ENST00000423535; = p.R78W on NM_001001663.3) | Missense Mutation (SNP) | VAF 191/521 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1024236807, COSV66954055; called by muse, mutect2, varscan2
- CYP2E1 | c.801C>G p.D267E | Missense Mutation (SNP) | VAF 111/517 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- INSR | c.2246G>T p.G749V | Missense Mutation (SNP) | VAF 155/461 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MCF2L | c.1349G>T p.R450M (on ENST00000375608; = p.R418M on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 401/912 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- MROH9 | c.2018C>T p.P673L | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- OOSP1 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TEX13D | c.1015C>A p.Q339K | Missense Mutation (SNP) | VAF 45/1350 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); called by muse, mutect2
- WDR89 | c.354del p.F118Lfs*33 | Frame Shift Del (DEL) | VAF 32/126 reads (25%) | called by mutect2, pindel, varscan2
- WRAP53 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 231/490 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- HYDIN | c.11229C>T p.P3743= | Silent (SNP) | VAF 104/334 reads (31%) | catalogued as rs376228603; called by muse, mutect2, varscan2
- OR6C2 | c.636G>A p.V212= | Silent (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
